Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A6RV, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A6RV-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: SOFT TISSUE, RIGHT THIGH, MASS, BIOPSY -
HIGH-GRADE LEIOMYOSARCOMA.

PART 2: SKIN AND SOFT TISSUE, RIGHT THIGH, MASS, RESECTION -

- A. HIGH-GRADE LEIOMYOSARCOMA, GRADE 3, 17.0 CM (see comment).
- B. MITOTIC FIGURES: 42/10 HIGH-POWER FIELDS, 80% NECROSIS.
- C. PROXIMAL MARGIN POSITIVE FOR MALIGNANCY, ALL OTHER MARGINS FREE OF TUMOR.
- D. ANGIOLYMPHATIC INVASION IDENTIFIED.
- E. PATHOLOGIC STAGE: pT2b Nx.
- F. PATHOLOGIC GRADE: GRADE 3.

COMMENT:

This malignant spindled cell neoplasm consists of fascicles of pleomorphic spindled cells with eosinophilic cytoplasm, blunt ended nuclei, coarse chromatin and some prominent nucleoli. Extensive necrosis (approximately 80%) and focal myxoid areas are observed. Angiolymphatic invasion is present. Brisk mitotic figures are noted and many are atypical (up to 42/10 high-powered fields). Immunohistochemical stains were performed and the cells of interest are positive for desmin (focally, blocks 2A, B), calponin (blocks 2A, B), smooth muscle actin (blocks 2A, B), CD99 and pancytokeratin, and negative for S-100, CD34 (highlights vascular structures) and C-kit. Ki-67 demonstrates up to 80% nuclear positivity. Osteocalcin and osteonectin show high background staining. The overall morphological and immunohistochemical results support high grade leiomyosarcoma.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY SOFT TISSUE TUMORS

SPECIMEN TYPE:

TUMOR SITE:

TUMOR DEPTH:

TUMOR SIZE:

PRERESECTION TREATMENT:

HISTOLOGIC TYPE (WHO classification of soft tissue tumors): leiomyosarcoma

RESULTS OF ANCILLARY STUDIES: see comment

MITOTIC RATE:

MACROSCOPIC NECROSIS:

MICROSCOPIC NECROSIS:

GRADE:

PATHOLOGIC STAGING (pTNM):

MARGINS:

MICROSCOPIC VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:

PERINEURAL INVASION:

SPECIAL PROCEDURES:

Cytogenetics

Interpretation

Marginal resection

right thigh

Deep: Subfascial

Deep: Intramuscular

Greatest dimension: 17 cm

Unknown

42 /10 high-power fields

Present: Extent: 80%

Present: Extent: 80%

System used: French Federation of Cancer Centers Sarcoma Group (FNCLCC)

Grade: grade 3

pT2b

pNX

Number regional lymph nodes examined: 0

Number regional lymph nodes involved: 0

pMX

Margins involved by sarcoma

Margin(s): proximal

Present

Absent

Apparently normal male chromosome analysis. No clonal numerical or structural abnormalities were observed. The possibility that the normal cells may represent normal stromal cells, and not the tumor cells, cannot be excluded. A few cells (see report below) with nonclonal chromosome abnormalities may be the result of a tissue culture artifact, but more likely represent the malignant cells.

RESULTS:

G-Banding

No. of Cells Analyzed: 20

No. of Cells Karyotyped: 6

No. of Chromosomes: <46 46

No. of Cells: 2 18

Twenty trypsin-Giemsa banded metaphase cells were analyzed from 4, 5, 6, and 7-day harvests of monolayer cell cultures from tissue labeled "right thigh mass." Fifteen cells had an apparently normal male chromosome complement. One cell had a hypodiploid karyotype, likely as a result of random chromosomal loss. One cell each had the following chromosome complement: 45,XY,t(3;12)(q21;q24.1),-19 and 46,XY,t(8;12)(q11.1;p11.1). Two cells from the same slide and the same microscopic field of vision both had a 46,XY,t(12;13)(q13;q14) chromosome complement.

Average band level/haploid set: 400

Source: NCI Genomic Data Commons file eddc79a7-e648-43f6-b2e1-37fc8f250cb0 (TCGA-K1-A6RV.0A448932-EEB0-4E9D-8B63-682E24BE2D0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).